Somatic mutation profile of tumor specimen MMRF_1886_1_BM_CD138pos (aliquot MMRF_1886_1_BM_CD138pos_T1_KBS5U_L05788) from MMRF case MMRF_1886, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,302 days).
Specimen MMRF_1886_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 573339a6-d894-496f-aee2-6f71ab072bd9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1886_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1886_1_PB_Whole_C3_KBS5U_L05810; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eee55ada-cf85-445d-9eb5-0330d108f188

The open-access MAF lists 97 somatic variants for this specimen: 36 protein-altering or splice-affecting, 13 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, 3'UTR 24, Intron 14, Silent 13, 5'Flank 4, 5'UTR 3, Frame Shift Del 3, RNA 2, Frame Shift Ins 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 31/62 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CIT | c.1259C>T p.S420L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as rs747895220, COSV55869199; called by muse, mutect2, varscan2
- DAND5 | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs747566940; called by muse, varscan2
- DZIP1 | c.2086G>A p.A696T (on ENST00000347108; = p.A677T on NM_014934.5) | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV61265254; called by muse, mutect2, varscan2
- EDNRB | c.1147del p.Y383Ifs*3 (on ENST00000377211 / NM_001201397.1; = p.Y293Ifs*3 on NM_000115.5) | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | catalogued as rs769735757; ClinVar: risk factor; called by mutect2, pindel, varscan2
- H1-4 | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV56803668; called by muse, mutect2, varscan2
- IGHV1-69D | c.155C>G p.A52G | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1367696485; called by mutect2, varscan2
- IGHV4-34 | c.322C>G p.L108V | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs374573009; called by muse, varscan2
- MEF2B | c.79G>A p.G27R | Missense Mutation (SNP) | VAF 35/75 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751538422; called by muse, mutect2, varscan2
- MTIF2 | c.1974dup p.F659Ifs*2 | Frame Shift Ins (INS) | VAF 6/10 reads (60%) | catalogued as rs770359991; called by mutect2, varscan2
- NRXN3 | c.655G>A p.D219N (on ENST00000557594 / NM_001272020.2; = p.D851N on NM_004796.6) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as rs990479889, COSV55326066; called by muse, mutect2, varscan2
- PCNX4 | c.1999A>G p.I667V (on ENST00000406854 / NM_001330177.2; = p.I433V on NM_022495.5) | Missense Mutation (SNP) | VAF 80/179 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as rs367873216; called by muse, mutect2, varscan2
- PSMC5 | c.212C>G p.S71C | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs1233105704, COSV56741216; called by muse, mutect2, varscan2
- SBK2 | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as rs554561970, COSV60013396; called by muse, mutect2, varscan2
- TSSK2 | c.676C>T p.R226C | Missense Mutation (SNP) | VAF 99/221 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as rs138737621; called by muse, mutect2, varscan2
- ABLIM2 | c.1070A>G p.Y357C | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCNB1 | c.1001A>G p.Y334C | Missense Mutation (SNP) | VAF 10/155 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- CDKN2C | c.65del p.T22Ifs*8 | Frame Shift Del (DEL) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- HERC2 | c.12149A>G p.H4050R | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IFIT1B | c.1049A>G p.Y350C | Missense Mutation (SNP) | VAF 107/222 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV2-70D | c.214A>C p.I72L | Missense Mutation (SNP) | VAF 46/48 reads (96%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, varscan2
- IGHV2-70D | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 12/14 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.026); called by mutect2, varscan2
- IGLV3-1 | c.252_254delinsTAT p.S85I | Missense Mutation (TNP) | VAF 11/73 reads (15%) | called by muse*, pindel
- KHDRBS3 | c.110del p.G37Efs*13 | Frame Shift Del (DEL) | VAF 45/114 reads (39%) | called by mutect2, pindel, varscan2
- NPAT | c.1726C>T p.H576Y | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUB1 | c.1126C>T p.H376Y | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- OVCH1 | c.1987T>C p.S663P | Missense Mutation (SNP) | VAF 136/283 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, varscan2
- PDE4DIP | c.4706T>A p.L1569H | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDIA6 | c.677A>C p.Q226P | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDK1 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ROPN1 | c.118T>A p.Y40N | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC7A6 | c.1201G>T p.V401L | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- TXNDC5 | c.414C>T p.T138= | Splice Region (SNP) | VAF 54/116 reads (47%) | called by muse, mutect2, varscan2
- USH2A | c.5659A>G p.N1887D | Missense Mutation (SNP) | VAF 132/182 reads (73%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- WDR43 | c.190T>A p.C64S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WT1 | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ARL5B | c.528T>A p.I176= | Silent (SNP) | VAF 110/228 reads (48%) | catalogued as COSV66011747; called by muse, mutect2, varscan2
- COL14A1 | c.5115C>T p.G1705= | Silent (SNP) | VAF 59/132 reads (45%) | catalogued as rs772178721, COSV52863802; called by muse, mutect2, varscan2
- COL16A1 | c.1314C>T p.G438= | Silent (SNP) | VAF 65/128 reads (51%) | catalogued as rs746510767; called by muse, mutect2, varscan2
- DSP | c.2641C>T p.L881= | Silent (SNP) | VAF 50/98 reads (51%) | called by muse, mutect2
- ECHDC3 | c.334C>T p.L112= | Silent (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- GALNT12 | c.306G>A p.Q102= | Silent (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- GLG1 | c.3258C>T p.R1086= | Silent (SNP) | VAF 20/34 reads (59%) | catalogued as rs148460697; called by muse, mutect2
- KCTD8 | c.429C>T p.V143= | Silent (SNP) | VAF 42/111 reads (38%) | catalogued as rs1225209478; called by muse, varscan2
- LTF | c.1944C>T p.D648= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV51608798; called by muse, mutect2, varscan2
- NCAPG2 | c.2394T>C p.D798= | Silent (SNP) | VAF 106/215 reads (49%) | called by muse, mutect2, varscan2
- OR4C16 | c.885C>T p.A295= | Silent (SNP) | VAF 64/158 reads (41%) | called by muse, mutect2, varscan2
- SLC14A2 | c.420C>T p.I140= | Silent (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2, varscan2
- TSPAN14 | c.240C>T p.C80= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as rs1046177887; called by muse, mutect2, varscan2
- ACTB | c.-27-230C>G | Intron (SNP) | VAF 9/15 reads (60%) | called by muse, mutect2, varscan2
- AL133467.6 | chr14:95668521 A>G | 5'Flank (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- B9D1 | c.-58C>G | 5'UTR (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- C4orf50 | c.*2147C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CCSER1 | c.1509+12608G>C | Intron (SNP) | VAF 26/68 reads (38%) | called by muse, mutect2, varscan2
- CDH19 | c.*3011del | 3'UTR (DEL) | VAF 19/49 reads (39%) | called by mutect2, pindel, varscan2
- CPSF7 | c.273+156A>C | Intron (SNP) | VAF 85/169 reads (50%) | called by muse, mutect2, varscan2
- DCUN1D5 | c.86+26C>G | Intron (SNP) | VAF 53/123 reads (43%) | called by muse, mutect2, varscan2
- DYNLT1 | c.272-46_272-37del | Intron (DEL) | VAF 75/200 reads (38%) | called by mutect2, pindel, varscan2
- ETV1 | chr7:13891876 T>G | 3'Flank (SNP) | VAF 70/132 reads (53%) | called by muse, mutect2, varscan2
- FANCM | c.5717-98T>A | Intron (SNP) | VAF 5/14 reads (36%) | called by muse, mutect2, varscan2
- GABBR2 | c.*476G>A | 3'UTR (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- GCSAML | c.*2696G>A | 3'UTR (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- H2BC21 | c.*136G>C | 3'UTR (SNP) | VAF 36/128 reads (28%) | called by muse, mutect2, varscan2
- HAUS6P3 | n.538A>C | RNA (SNP) | VAF 42/89 reads (47%) | called by muse, mutect2, varscan2
- HUS1 | c.*462G>A | 3'UTR (SNP) | VAF 34/68 reads (50%) | catalogued as rs1299623679; called by muse, mutect2, varscan2
- IGHV3-7 | c.-24A>C | 5'UTR (SNP) | VAF 84/85 reads (99%) | called by muse, mutect2
- IMMP2L | c.305+857G>A | Intron (SNP) | VAF 19/44 reads (43%) | called by muse, mutect2, varscan2
- KAZN | c.-862T>C | 5'UTR (SNP) | VAF 115/209 reads (55%) | called by muse, mutect2, varscan2
- KLF9 | c.*735A>C | 3'UTR (SNP) | VAF 26/59 reads (44%) | called by muse, mutect2, varscan2
- LUC7L2 | c.*45dup | 3'UTR (INS) | VAF 90/214 reads (42%) | called by mutect2, pindel, varscan2
- MIR5195 | chr14:106851224 G>C | 5'Flank (SNP) | VAF 85/161 reads (53%) | catalogued as rs544431037; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851314 G>C | 5'Flank (SNP) | VAF 64/136 reads (47%) | catalogued as rs573318832; called by muse, mutect2, varscan2
- MYO9A | c.*3902G>T | 3'UTR (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- MYOZ2 | c.*1563del | 3'UTR (DEL) | VAF 21/41 reads (51%) | called by mutect2, pindel, varscan2
- NPFFR2 | c.*242G>A | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- NRXN1 | c.*2455G>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- NWD2 | c.*400T>G | 3'UTR (SNP) | VAF 47/103 reads (46%) | called by muse, mutect2, varscan2
- OSER1 | c.*246G>A | 3'UTR (SNP) | VAF 28/64 reads (44%) | called by muse, mutect2, varscan2
- OSGIN1 | n.990G>A | RNA (SNP) | VAF 55/131 reads (42%) | catalogued as rs959600399, COSV59675793; called by muse, mutect2, varscan2
- OVCH1 | c.1930-22T>C | Intron (SNP) | VAF 94/188 reads (50%) | called by muse, varscan2
- PHB2 | c.*3C>G | 3'UTR (SNP) | VAF 56/122 reads (46%) | catalogued as rs782337305; called by muse, mutect2, varscan2
- PRELP | c.*1131G>C | 3'UTR (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- PRKN | c.734+199T>G | Intron (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
- RECQL5 | c.*70G>A | 3'UTR (SNP) | VAF 27/39 reads (69%) | called by muse, mutect2, varscan2
- SLC22A6 | c.*127C>T | 3'UTR (SNP) | VAF 79/176 reads (45%) | called by muse, varscan2
- SLC26A4 | c.*2141T>C | 3'UTR (SNP) | VAF 24/64 reads (38%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1203+197G>A | Intron (SNP) | VAF 14/15 reads (93%) | called by muse, mutect2, varscan2
- TRIM13 | c.*1721G>A | 3'UTR (SNP) | VAF 35/76 reads (46%) | called by muse, mutect2, varscan2
- TTC19 | c.*633T>C | 3'UTR (SNP) | VAF 41/71 reads (58%) | called by muse, mutect2, varscan2
- UBC | c.-4+354G>A | Intron (SNP) | VAF 101/203 reads (50%) | catalogued as rs1158062311; called by muse, mutect2, varscan2
- VAV2 | c.*1287C>T | 3'UTR (SNP) | VAF 29/78 reads (37%) | called by muse, mutect2, varscan2
- VCAN | c.1042+44dup | Intron (INS) | VAF 49/116 reads (42%) | catalogued as rs747471495; called by mutect2, varscan2
- WDR77 | c.801-14C>G | Intron (SNP) | VAF 14/15 reads (93%) | called by muse, mutect2, varscan2
- ZIC1 | c.*694A>C | 3'UTR (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- ZNF41 | chrX:47483906 T>A | 5'Flank (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- ZNF497 | c.-111-941C>T | Intron (SNP) | VAF 52/91 reads (57%) | catalogued as rs751916471, COSV100218302; called by muse, mutect2, varscan2
- ZNF786 | c.*625T>G | 3'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
